Gene-level copy-number profile of tumor specimen TCGA-B0-5109-01A from TCGA case TCGA-B0-5109, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 69.6 years (25,428 days).
Specimen TCGA-B0-5109-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.17c263fc-2b82-4bcd-91b0-f8dc9c5302a3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B0-5109-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/15557a7f-71ab-474e-af5e-982c6cd07e10

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 33,328; copy number 2: 24,385; copy number 3: 2,080.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B0-5109-01A-02D-1417-01): tumor purity 0.26, ploidy 2.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,730,055–60,856,605, 3 genes: AC104164.1, PPIAP71, U3.
- chr3:77,316,752–77,317,598, 1 gene: VDAC1P7.
- chr4:181,260,442–181,265,145, 1 gene: LINC02500.
- chr6:158,232,236–158,511,828, 1 gene (within-gene range 0–1): TULP4.
- chr6:158,282,841–158,428,379, 3 genes (within-gene range 0–1): AL360169.2, AL360169.3, AL360169.1.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr12:9,641,723–9,699,553, 6 genes (within-gene range 0–2): GOT2P3, AC010186.4, AC010186.1, AC010186.2, AC010186.3, CLEC2D.
- chr15:56,918,623–57,299,281, 2 genes (within-gene range 0–1): TCF12, HNRNPA3P11.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 2,080 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,555,040–241,357,230, 53 genes, copy number 3 (within-gene range 1–3): AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123.
- chr5:149,425,771–171,411,810, 313 genes, copy number 3 (broad region; genes not listed).
- chr5:171,420,016–171,436,172, 1 gene, copy number 3 (within-gene range 2–3): AC093246.1.
- chr11:20,669,551–21,575,686, 1 gene, copy number 3 (within-gene range 2–3): NELL1.
- chr11:21,000,881–21,843,210, 6 genes, copy number 3: RNA5SP336, AC090857.1, AC090857.2, AC099730.1, RNA5SP337, AC130307.1.
- chr17:50,184,101–83,095,122, 977 genes, copy number 3 (broad region; genes not listed).
- chr19:27,638,483–45,092,635, 728 genes, copy number 3 (broad region; genes not listed).
- chr19:45,091,396–45,148,077, 1 gene, copy number 3 (within-gene range 1–3): PPP1R37.

Autosomal genes at a single copy (total copy number 1): 30,915. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
